MMRF case MMRF_1556 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ec71e12b-ead0-4dbb-96ce-5897906be766

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.6 years (26,148 days); Days to last known disease status: 1,268 days (3.5 years); Days to last follow up: 1,268 days (3.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 113 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,212 days (3.3 years); Days to treatment end: 1,337 days (3.7 years).
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,212 days (3.3 years); Days to treatment end: 1,335 days (3.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 2): M Protein 0.06 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 24.2 mg/dL; Immunoglobulin G 2.93 g/L; Immunoglobulin A 0.75 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 9.9 ×10⁹/L; Absolute Neutrophil 6.7 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 200 µmol/L; Blood Urea Nitrogen 16.4 mmol/L; Calcium 2.05 mmol/L; Albumin 25 g/L; Total Protein 4.6 g/dL; Glucose 7.92 mmol/L.
- Day 93 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.03 mg/dL; Immunoglobulin G 2.86 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 8.97 µg/mL; Lactate Dehydrogenase 4.28 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 9.4 ×10⁹/L; Absolute Neutrophil 7.4 ×10⁹/L; Platelets 258 ×10⁹/L; Creatinine 212 µmol/L; Blood Urea Nitrogen 15 mmol/L; Calcium 2.05 mmol/L; Albumin 27 g/L; Total Protein 4.5 g/dL; Glucose 6.88 mmol/L.
- Day 184 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.29 mg/dL; Immunoglobulin G 3.25 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.17 g/L; Hemoglobin 7.63 mmol/L; Leukocytes 10 ×10⁹/L; Absolute Neutrophil 8 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 223 µmol/L; Blood Urea Nitrogen 21.1 mmol/L; Calcium 2.15 mmol/L; Albumin 32 g/L; Glucose 5.94 mmol/L.
- Day 267 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.52 mg/dL; Immunoglobulin G 4.94 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 0.35 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 10.4 ×10⁹/L; Absolute Neutrophil 8.1 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 282 µmol/L; Blood Urea Nitrogen 26.8 mmol/L; Calcium 2.38 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 6.27 mmol/L.
- Day 351 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.55 mg/dL; Immunoglobulin G 5.06 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 11.4 ×10⁹/L; Absolute Neutrophil 8.4 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 257 µmol/L; Blood Urea Nitrogen 29.3 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 5.6 g/dL; Glucose 5.56 mmol/L.
- Day 446 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.76 mg/dL; Immunoglobulin G 5.24 g/L; Immunoglobulin A 0.72 g/L; Immunoglobulin M 0 g/L; Hemoglobin 7.63 mmol/L; Leukocytes 11.5 ×10⁹/L; Absolute Neutrophil 9 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 251 µmol/L; Blood Urea Nitrogen 30 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 5.7 g/dL; Glucose 5.34 mmol/L.
- Day 523 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.19 mg/dL; Immunoglobulin G 6.33 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.38 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 9.7 ×10⁹/L; Absolute Neutrophil 7.6 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 225 µmol/L; Blood Urea Nitrogen 23.6 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 5.78 mmol/L.
- Day 642 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.96 mg/dL; Immunoglobulin G 6.11 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 11.8 ×10⁹/L; Absolute Neutrophil 9.3 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 222 µmol/L; Blood Urea Nitrogen 22.8 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.12 mmol/L.
- Day 691 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.37 mg/dL; Immunoglobulin G 6.28 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 10.8 ×10⁹/L; Absolute Neutrophil 7.8 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 234 µmol/L; Blood Urea Nitrogen 16.8 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 5.5 mmol/L.
- Day 824 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.12 mg/dL; Immunoglobulin G 3.11 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 10.8 ×10⁹/L; Absolute Neutrophil 8.7 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 226 µmol/L; Blood Urea Nitrogen 17.1 mmol/L; Calcium 2.43 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 5.28 mmol/L.
- Day 876 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.03 mg/dL; Immunoglobulin G 5.66 g/L; Immunoglobulin A 5.66 g/L; Immunoglobulin M 0.39 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 10.8 ×10⁹/L; Absolute Neutrophil 8.3 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 249 µmol/L; Blood Urea Nitrogen 24.6 mmol/L; Calcium 2.43 mmol/L; Albumin 36 g/L; Total Protein 5.8 g/dL; Glucose 4.9 mmol/L.
- Day 1,006 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.17 mg/dL; Immunoglobulin G 5.56 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 0.45 g/L; Hemoglobin 8.93 mmol/L; Leukocytes 11.5 ×10⁹/L; Absolute Neutrophil 8.8 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 268 µmol/L; Blood Urea Nitrogen 19.6 mmol/L; Calcium 2.43 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 6.66 mmol/L.
- Day 1,069 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.11 mg/dL; Immunoglobulin G 4.64 g/L; Immunoglobulin A 0.94 g/L; Immunoglobulin M 0.36 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 10.7 ×10⁹/L; Absolute Neutrophil 8.4 ×10⁹/L; Platelets 317 ×10⁹/L; Creatinine 332 µmol/L; Blood Urea Nitrogen 22.1 mmol/L; Calcium 2.48 mmol/L; Albumin 34 g/L; Total Protein 5.8 g/dL; Glucose 5.28 mmol/L.
- Day 1,160 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.76 mg/dL; Immunoglobulin G 4.59 g/L; Immunoglobulin A 0.89 g/L; Immunoglobulin M 0.36 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 10 ×10⁹/L; Absolute Neutrophil 7.6 ×10⁹/L; Platelets 302 ×10⁹/L; Creatinine 310 µmol/L; Blood Urea Nitrogen 21.8 mmol/L; Calcium 2.23 mmol/L; Albumin 33 g/L; Total Protein 5.5 g/dL; Glucose 5.06 mmol/L.
- Day 1,268: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 10.2 mg/dL; Immunoglobulin G 3.13 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 11.2 ×10⁹/L; Absolute Neutrophil 9.2 ×10⁹/L; Platelets 305 ×10⁹/L; Creatinine 402 µmol/L; Blood Urea Nitrogen 22.1 mmol/L; Calcium 2.18 mmol/L; Albumin 30 g/L; Total Protein 5.1 g/dL; Glucose 6.16 mmol/L.

Other clinical attributes
- Day -5: Weight: 74 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1556_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_1556_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
